Somatic mutation profile of tumor specimen MP2PRT-PAPWDV-TMP1-A (aliquot MP2PRT-PAPWDV-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPWDV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,106 days).
Specimen MP2PRT-PAPWDV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c7656b0-aa14-4755-862b-c8bcd4f30357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWDV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWDV-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad4ab0ef-6a36-4f41-aa90-9fe796f78d5f

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Splice Site 2, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 99/261 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.3940G>A p.V1314I (on ENST00000398564; = p.V1289I on NM_014629.4) | Missense Mutation (SNP) | VAF 44/781 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100033990; called by muse, mutect2
- CNTN6 | c.1493-1G>T p.X498_splice | Splice Site (SNP) | VAF 92/174 reads (53%) | catalogued as CS1410395, COSV100610290; called by muse, mutect2, varscan2
- COL3A1 | c.2023-1G>T p.X675_splice | Splice Site (SNP) | VAF 68/175 reads (39%) | catalogued as rs587779708, CS098066; called by muse, mutect2, varscan2
- DNAH5 | c.4703G>A p.R1568H | Missense Mutation (SNP) | VAF 118/347 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs200994058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.5285C>T p.T1762M | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs917672791, COSV62453282; called by muse, mutect2, varscan2
- NIPBL | c.5471C>T p.S1824L | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM107657; called by muse, mutect2, varscan2
- USP17L7 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 134/626 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs763250677; called by muse, mutect2, varscan2
- CFAP46 | c.5358dup p.R1787Afs*15 | Frame Shift Ins (INS) | VAF 80/274 reads (29%) | called by mutect2, varscan2
- CFAP46 | c.5357delinsGG p.E1786Gfs*16 | Frame Shift Ins (INS) | VAF 94/416 reads (23%) | called by mutect2*, pindel, varscan2*
- FBXO27 | c.791C>A p.A264D | Missense Mutation (SNP) | VAF 345/384 reads (90%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LINC00514 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NFATC3 | c.519G>T p.R173S | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SHROOM3 | c.1394C>A p.T465N | Missense Mutation (SNP) | VAF 132/577 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CCR4 | c.588G>A p.T196= | Silent (SNP) | VAF 103/228 reads (45%) | catalogued as rs138870584; called by muse, mutect2, varscan2
- KBTBD13 | c.771C>T p.D257= | Silent (SNP) | VAF 298/640 reads (47%) | catalogued as rs1455562237; called by muse, mutect2
- KIF7 | c.1953G>A p.A651= | Silent (SNP) | VAF 111/274 reads (41%) | catalogued as rs764831222; called by muse, mutect2, varscan2
- LTBP1 | c.3336G>A p.S1112= (on ENST00000404816 / NM_206943.4; = p.S786= on NM_000627.4) | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as rs139837372; called by muse, mutect2, varscan2
- MORC3 | c.2493C>T p.D831= | Silent (SNP) | VAF 46/253 reads (18%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1023C>T p.N341= | Silent (SNP) | VAF 136/396 reads (34%) | catalogued as rs1321583045, COSV53893771; called by muse, mutect2, varscan2
- PLXNA4 | c.1248C>T p.S416= | Silent (SNP) | VAF 161/534 reads (30%) | catalogued as rs374767499, COSV58126348; called by muse, mutect2, varscan2
- TBC1D29P | n.2760G>A | RNA (SNP) | VAF 127/399 reads (32%) | called by muse, mutect2, varscan2
